HCMI case HCM-BROD-0681-C71 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/816e3eb6-1d9c-4f79-b672-c76b3af02d1c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1967; Vital status: Dead; Days to death: 1,351 days (3.7 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 50.2 years (18,343 days); WHO CNS grade: Grade IV; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -1 day.
   Treatment given: Treatment type: Radiation, 3D Conformal; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 41 days; Days to treatment end: 956 days (2.6 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 41 days; Days to treatment end: 289 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Nivolumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 629 days (1.7 years); Days to treatment end: 862 days (2.4 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Targeted Molecular Therapy, for residual disease.
2. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: recurrence; Age at diagnosis: 52.6 years (19,225 days); Days to diagnosis: 882 days (2.4 years).
   Pathology details: Necrosis present: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Nivolumab + Temozolomide; Treatment intent type: Maintenance Therapy; Days to treatment start: 41 days; Days to treatment end: 862 days (2.4 years); Treatment outcome: Treatment Ongoing.

Follow-up (3 entries)
- Days to follow up: 903 days (2.5 years); Karnofsky performance status: 90.
- Days to follow up: 1,321 days (3.6 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contacts recording only the day: day 886, day 1,064.

Molecular and laboratory tests
- IDH1 (IHC): Negative; Amino-acid change: R132H.
- IDH1 / IDH2 (Targeted Sequencing): Negative.
- MGMT methylation: Positive.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 34.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0681-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0681-C71-02A-01-S1-HE: Section location: Top; Percent tumor cells: 79; Percent tumor nuclei: 90; Percent normal cells: 8; Percent necrosis: 0; Percent stromal cells: 13; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0681-C71-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0681-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
